Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UX, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UX-01A (Primary Tumor).

[page 1 of 2]
Print Malignancy History		☒
Case is (Inc):		

ad & Neck
ad And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

FNA for suspicious papillary thyroid cancer.

Specimens Submitted:

1: Thyroid gland; total thyroidectomy

DIAGNOSIS:

1. Thyroid gland; total thyroidectomy:
Tumor Type:
Papillary microcarcinoma.

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Other Tumor Features:
Marked stromal reaction

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 0.5 cm.

Tumor Encapsulation:
None identified

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

Non-Neoplastic Thyroid:
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5-2-12 RD

[page 2 of 2]
Not identified

Lymph Nodes:

Three benign perithyroid lymph nodes.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh, labeled "Total thyroidectomy" and consists of a thyroid weighing 8.5 g. The right lobe measures 2.0 x 2.0 x 0.5 cm, the left lobe measures 4.0 x 2.0 x 1.3 cm, the isthmus measures 3.0 x 1.5 cm and pyramidal lobe is 3.0 x 1.0 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals two white firm nodules in the right lobe measuring 0.3 x 0.3 x 0.2 and 0.5 x 0.4 x 0.3 cm. The larger nodule abuts the anterior capsule. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for _____ and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

SN - smaller nodule
LN--larger nodule
RL - right lobe
LL - left lobe
I - isthmus
P--pyramidal lobe

Summary of Sections:

Part 1: Thyroid gland; total thyroidectomy

Block	Sect. Site	PCs
3	I	6
5	LL	10
1	LN	2
3	P	6
2	RL	4
1	SN	2

Source: NCI Genomic Data Commons file 80255daa-4cbb-400b-8a88-01c938ce3e64 (TCGA-DJ-A3UX.8791C9F6-CB05-47BE-900F-76A896823EC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).